Gene-level copy-number profile of tumor specimen TARGET-10-PATEAK-09A from TARGET case TARGET-10-PATEAK, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 17.9 years (6,551 days).
Specimen TARGET-10-PATEAK-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.aa022c3b-cd39-5d8a-9f9c-e60871b0684a.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PATEAK-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 394 have no estimate.
https://portal.gdc.cancer.gov/files/8dee4a6f-a643-4fb4-81a6-18d25c9c4c21

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 108; copy number 1: 2,540; copy number 2: 55,135; copy number 3: 2,432; copy number 4: 13; copy number 5: 1.

Homozygous deletions (total copy number 0; autosomes only): 108 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,256,337–38,340,998, 15 genes: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,350,022, 2 genes: TRGV5P, TRGV5.
- chr9:21,135,598–22,128,103, 50 genes: AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr14:22,096,032–22,482,959, 41 genes: TRDV1, TRAV24, TRAV25, TRAV26-1, TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:20,155,618–20,156,057, 1 gene, copy number 5: RPS16P2.

Autosomal genes at a single copy (total copy number 1): 153. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
